Gene-level copy-number profile of tumor specimen TCGA-FU-A23L-01A from TCGA case TCGA-FU-A23L, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIA1; Tumor grade: G3; Age at diagnosis: 60.1 years (21,962 days).
Specimen TCGA-FU-A23L-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.6e084af6-abdb-4c50-9adf-49089dcf9276.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FU-A23L-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/abe0bae9-6cf6-4bc7-bbe7-6f034b7d3900

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 471; copy number 2: 16,479; copy number 3: 26,254; copy number 4: 10,445; copy number 5: 2,408; copy number 6: 2,982; copy number 7: 764; copy number 8: 6; copy number 13: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FU-A23L-01A-11D-A16M-01): tumor purity 0.5, ploidy 3.48, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,618,079, 2 genes: AC104164.2, MIR548BB.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 775 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:106,780,223–109,509,738, 59 genes, copy number 7: AL596327.1, MTATP6P14, MTCO1P14, LINC01661, PRMT6, NTNG1, NDUFA4P1, VAV3, MIR7852, VAV3-AS1, LINC02785, SLC25A24, AL359258.2, AL359258.3, NBPF4, AL359258.1, SLC25A24P1, NBPF5P, SLC25A24P2, AL390038.1, NBPF6, AL392088.2, ST13P21, AL392088.1, FAM102B, HENMT1, AL160171.1, PRPF38B, FNDC7, AL591719.2, STXBP3, AL591719.1, AKNAD1, SPATA42, GPSM2, CLCC1, WDR47, BX679664.2, BX679664.3, BX679664.1, RANP5, TAF13, AL356488.3, TMEM167B, SCARNA2, AL356488.2, AL356488.1, C1orf194, ELAPOR1, SARS1, CELSR2, PSRC1, MYBPHL, SORT1, PSMA5, SYPL2, ATXN7L2, CYB561D1, AMIGO1.
- chr1:171,083,565–171,212,686, 6 genes, copy number 8: BX284613.1, FMO3, MIR1295A, MIR1295B, FMO6P, FMO2.
- chr5:58,198–30,248,893, 452 genes, copy number 7 (broad region; genes not listed).
- chr5:31,193,686–45,895,970, 252 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr6:63,797,189–64,631,682, 5 genes, copy number 13: AL354719.1, SCAT8, GCNT1P4, AL357375.1, HNRNPDP2.
- chr8:127,400,399–127,402,150, 1 gene, copy number 7: CCAT2.

Autosomal genes at a single copy (total copy number 1): 471. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
